Somatic mutation profile of tumor specimen C3N-00556-03 (aliquot CPT0090700009) from CPTAC case C3N-00556, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 69.7 years (25,462 days).
Specimen C3N-00556-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d836096-bd01-4538-836e-49a52487bc43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00556-31 (Blood Derived Normal), aliquot CPT0090800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82b3d2d5-05e5-463f-93b7-8b9797ff72fd

The open-access MAF lists 703 somatic variants for this specimen: 478 protein-altering or splice-affecting, 141 silent, 84 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 409, Silent 141, Nonsense Mutation 45, Intron 34, 3'UTR 17, RNA 15, 5'UTR 11, Splice Site 9, Frame Shift Del 6, 5'Flank 5, Frame Shift Ins 4, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 110/341 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AADACL3 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60199984; called by muse, mutect2, varscan2
- ABCA13 | c.11246G>T p.G3749V | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs769810894, COSV101447139, COSV71284937, COSV71293911; called by muse, mutect2, varscan2
- AC004922.1 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV53559302; called by muse, mutect2
- ACSM4 | c.1522C>G p.Q508E | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV68068922; called by muse, mutect2, varscan2
- ACTL8 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 26/242 reads (11%) | catalogued as COSV100958729; called by muse, mutect2, varscan2
- AGBL1 | c.2140A>T p.T714S | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV66857359, COSV66876354, COSV99069532; called by muse, mutect2
- AL592490.1 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs751419926; called by muse, mutect2, varscan2
- AMIGO3 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.041); catalogued as rs769710626; called by muse, mutect2, varscan2
- ANAPC2 | c.2213C>T p.S738F | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60572637; called by muse, mutect2
- ANK2 | c.7051G>A p.E2351K | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.031); catalogued as COSV52197117; called by muse, mutect2, varscan2
- ANKRD18A | c.1632G>C p.E544D | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1563965863; called by muse, mutect2
- ANLN | c.3074G>A p.R1025H | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs544165747, COSV99732157; called by muse, mutect2, varscan2
- AOC3 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs530957915, COSV53824905; called by muse, mutect2
- AOPEP | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 24/362 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1303149313; called by muse, mutect2
- APC | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV57348738, COSV57363838, COSV57384634; called by muse, mutect2
- ARL8A | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV99693373; called by muse, mutect2, varscan2
- BEND3 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.578); catalogued as rs782181324; called by muse, mutect2
- BGN | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.347); catalogued as COSV100525209; called by muse, mutect2, varscan2
- BICDL2 | c.1074G>C p.E358D | Missense Mutation (SNP) | VAF 38/369 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as rs1325370196; called by muse, mutect2, varscan2
- BMPR2 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65811667; called by muse, mutect2
- C12orf40 | c.1544G>C p.R515T | Missense Mutation (SNP) | VAF 11/319 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV61137187; called by muse, mutect2
- C3orf20 | c.1137C>G p.F379L | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV53786973; called by muse, mutect2
- C8orf58 | c.234C>G p.S78R | Missense Mutation (SNP) | VAF 14/315 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1259558308; called by muse, mutect2
- CANT1 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 18/431 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.093); catalogued as rs1161499032; called by muse, mutect2
- CANT1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 32/592 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.484); catalogued as rs1443282700; called by muse, mutect2
- CD1A | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs141426527, COSV56860802; called by muse, mutect2, varscan2
- CDON | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); catalogued as rs1304476416; called by muse, mutect2
- CEP131 | c.2884G>A p.E962K (on ENST00000269392 / NM_001319228.2; = p.E959K on NM_014984.4) | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs755773021, COSV99487726; called by muse, mutect2, varscan2
- CHD3 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1178138055, COSV57875109; called by muse, mutect2, varscan2
- CLEC4D | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV55229459; called by muse, mutect2, varscan2
- COL28A1 | c.2470A>G p.M824V | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs370169963; called by muse, mutect2, varscan2
- COX15 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV50012705; called by muse, mutect2
- CSMD3 | c.965G>T p.W322L | Missense Mutation (SNP) | VAF 93/298 reads (31%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as COSV52286667; called by muse, mutect2, varscan2
- CSNK2A3 | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 33/413 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99925576; called by muse, mutect2
- CWF19L2 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs746301566; called by muse, mutect2, varscan2
- DDIT4L | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56768035; called by muse, mutect2
- DHX9 | c.2300G>A p.R767Q | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62360747; called by muse, varscan2
- DIP2A | c.2297C>T p.T766M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs1569081810; called by muse, mutect2, varscan2
- DMXL1 | c.4363G>A p.D1455N | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs1458470031; called by muse, mutect2
- DNAH7 | c.5359G>A p.D1787N | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV56757099; called by muse, mutect2
- DPH7 | c.737A>G p.Q246R | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1214915751; called by muse, mutect2, varscan2
- DTNA | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 15/412 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV99310325; called by muse, mutect2
- DYNC2H1 | c.8177T>A p.I2726N | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1255448358; called by muse, mutect2
- EBF1 | c.382G>C p.V128L | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs1427845418; called by muse, mutect2, varscan2
- ELF2 | c.1292C>G p.P431R (on ENST00000379550 / NM_001331036.2; = p.P371R on NM_006874.4) | Missense Mutation (SNP) | VAF 22/516 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV55491892; called by muse, mutect2
- ENO3 | c.1068-1G>T p.X356_splice | Splice Site (SNP) | VAF 53/265 reads (20%) | catalogued as rs371648627; called by muse, mutect2, varscan2
- EPHA5 | c.1610T>C p.V537A | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as COSV56684120; called by muse, mutect2
- EPO | c.186G>T p.L62F | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV53161769; called by muse, mutect2, varscan2
- ERICH6 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs112279628, COSV99901328; called by muse, varscan2
- FAM13C | c.1345G>T p.D449Y | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53244054; called by muse, mutect2, varscan2
- FAM171A1 | c.533T>C p.V178A | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1351171938; called by muse, mutect2, varscan2
- FBRSL1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1284852354; called by muse, mutect2, varscan2
- FGFRL1 | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 18/108 reads (17%) | catalogued as rs747346476; called by muse, mutect2, varscan2
- FRY | c.1903C>T p.H635Y | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969949; called by muse, mutect2
- GAD1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); catalogued as COSV100713921, COSV100713926; called by muse, mutect2
- GCN1 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV56116281; called by muse, mutect2
- GIT2 | c.1082C>G p.S361C (on ENST00000355312 / NM_057169.5; = p.S363C on NM_014776.5) | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as COSV58081429; called by muse, mutect2
- GLIS3 | c.1271C>G p.S424* | Nonsense Mutation (SNP) | VAF 14/308 reads (5%) | catalogued as COSV100173136, COSV100174787; called by muse, mutect2
- GMCL1 | c.408C>G p.F136L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.524); catalogued as COSV99247971; called by muse, mutect2
- GNAT2 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1310692549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPI | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV62894258; called by muse, mutect2
- GREB1 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99302869; called by muse, mutect2, varscan2
- GRM5 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs752621407, COSV59607226, COSV59613591; called by muse, mutect2, varscan2
- H2AC20 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 35/550 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58613363; called by muse, mutect2
- HMOX1 | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs763151157; called by muse, mutect2, varscan2
- HNF1A | c.886G>T p.G296* | Nonsense Mutation (SNP) | VAF 51/218 reads (23%) | catalogued as COSV57466755, COSV57467364; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs375123342; called by muse, mutect2, varscan2
- HTR1A | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 86/390 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV60500648; called by muse, mutect2, varscan2
- HYAL2 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99222693; called by muse, mutect2
- IGLON5 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs867277204; called by muse, mutect2, varscan2
- IL18 | c.548G>C p.R183T | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1447899521, COSV54781276; called by muse, mutect2
- INTS4 | c.674G>C p.R225T | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs1565273985; called by muse, mutect2
- IQCJ-SCHIP1 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.242); catalogued as COSV67333758; called by muse, mutect2, varscan2
- KAT2B | c.1112C>G p.S371* | Nonsense Mutation (SNP) | VAF 6/150 reads (4%) | catalogued as COSV55426997; called by muse, mutect2
- KMT2B | c.1951C>G p.Q651E | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV52892888; called by muse, mutect2
- KNTC1 | c.4924G>A p.V1642I | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.23); catalogued as rs1247882200; called by muse, mutect2
- KRT14 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.274); catalogued as rs60622724, CM032005; called by muse, mutect2, varscan2
- KRT2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 36/182 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as rs544808368; called by muse, mutect2, varscan2
- KRTAP19-5 | c.65del p.G22Afs*56 | Frame Shift Del (DEL) | VAF 36/366 reads (10%) | catalogued as COSV61858546; called by mutect2, pindel
- LAMC3 | c.3492G>T p.R1164S | Missense Mutation (SNP) | VAF 21/361 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV63094391; called by muse, mutect2
- LCE1F | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 55/360 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV57670129; called by muse, mutect2, varscan2
- LGALSL | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV53230388; called by muse, mutect2, varscan2
- LMOD1 | c.1041C>G p.I347M | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV66172950, COSV66173769; called by muse, mutect2
- LMX1A | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1188555257; called by muse, mutect2, varscan2
- MAML3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 31/395 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs931430833, COSV72210183; called by muse, mutect2
- MAP3K4 | c.3983A>G p.Y1328C | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs141444159; called by muse, mutect2, varscan2
- MAP4K2 | c.1342A>G p.M448V | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs372194687; called by muse, mutect2, varscan2
- MB21D2 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 14/233 reads (6%) | catalogued as COSV66662797; called by muse, mutect2
- MB21D2 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 23/133 reads (17%) | catalogued as COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MPDZ | c.3064G>T p.V1022F | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762601542; called by muse, mutect2, varscan2
- MYCBP2 | c.9231C>G p.I3077M (on ENST00000357337; = p.I3115M on NM_015057.5) | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as COSV62010109; called by muse, mutect2, varscan2
- MYL10 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.972); catalogued as COSV56207093; called by muse, mutect2, varscan2
- MYO3B | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100511527; called by muse, mutect2, varscan2
- MYO9B | c.3178G>T p.E1060* | Nonsense Mutation (SNP) | VAF 18/418 reads (4%) | catalogued as COSV68278016; called by muse, mutect2
- NAA16 | c.1990C>G p.L664V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs763907713, COSV65130703; called by muse, mutect2, varscan2
- NEK8 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 43/500 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs1199087140, COSV52047226; called by muse, mutect2
- NELFB | c.930C>A p.F310L | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs761641101; called by muse, mutect2, varscan2
- NID1 | c.2513G>A p.R838H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs760250427, COSV51614677; called by muse, mutect2, varscan2
- NIFK | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs141833997; called by muse, mutect2, varscan2
- NOXRED1 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.022); catalogued as COSV100033179; called by muse, mutect2, varscan2
- ODAM | c.528+1G>A p.X176_splice | Splice Site (SNP) | VAF 12/136 reads (9%) | catalogued as rs773555999; called by muse, mutect2
- OR10X1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs144668774; called by muse, mutect2, varscan2
- OR12D3 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.982); catalogued as rs1398430526; called by muse, mutect2, varscan2
- OR4S1 | c.97C>T p.H33Y | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100180311; called by muse, mutect2
- OR51G1 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58968273; called by muse, mutect2
- PAGE2 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV66595830; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.268G>C p.E90Q (on ENST00000374531 / NM_001037293.2; = p.E88Q on NM_007203.5) | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57129934; called by muse, mutect2
- PANX2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs1485043074, COSV50293248, COSV50308756; called by muse, mutect2
- PCDHB12 | c.2129C>A p.A710E | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); catalogued as COSV99507056; called by muse, mutect2, varscan2
- PCDHGB7 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 77/313 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54049774; called by muse, mutect2, varscan2
- PCNT | c.4096G>T p.E1366* | Nonsense Mutation (SNP) | VAF 16/357 reads (4%) | catalogued as rs1323043278; called by muse, mutect2
- PDCD1LG2 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67204978; called by muse, mutect2
- PDIA3 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.724); catalogued as COSV55857931; called by muse, mutect2
- PLCE1 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 24/537 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.445); catalogued as COSV99596182; called by muse, mutect2
- PLCE1 | c.3953C>G p.S1318C | Missense Mutation (SNP) | VAF 23/467 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1344374749; called by muse, mutect2
- POLD1 | c.1055G>T p.R352L | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs556862476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRG4 | c.3982C>T p.Q1328* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100798175; called by muse, mutect2
- PRMT5 | c.1895C>G p.S632* | Nonsense Mutation (SNP) | VAF 20/164 reads (12%) | catalogued as COSV53545624; called by muse, mutect2, varscan2
- PTGER4 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.115); catalogued as COSV56721920; called by muse, mutect2
- RAC3 | c.323C>A p.T108K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as COSV60711403; called by muse, mutect2, varscan2
- RBM46 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as rs763804182, COSV55982621; called by muse, mutect2
- RCC1 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV65779525; called by muse, mutect2
- RETREG3 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.022); catalogued as COSV99519004; called by muse, mutect2
- RETREG3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.058); catalogued as rs764953063; called by muse, mutect2
- RGS14 | c.806G>T p.S269I | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1211123044; called by muse, mutect2, varscan2
- RUNX1 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV100297566, COSV55880380; called by muse, mutect2
- RYR2 | c.2008T>G p.Y670D | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63667661; called by muse, mutect2
- SCN1A | c.4699G>A p.E1567K (on ENST00000303395 / NM_001202435.3; = p.E1556K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1037225738; called by muse, mutect2
- SCN3A | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV51810880; called by muse, mutect2
- SEC14L3 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1402541394, COSV101302995; called by muse, mutect2, varscan2
- SEC24C | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.177); catalogued as rs1406595070, COSV59545364; called by muse, mutect2
- SEMA5A | c.2810G>T p.S937I | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV101228777; called by muse, mutect2, varscan2
- SFT2D1 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.09); catalogued as rs1332955660; called by muse, mutect2
- SI | c.4271T>C p.L1424P | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52279273; called by muse, mutect2, varscan2
- SIRT1 | c.819C>A p.F273L | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53019927; called by muse, mutect2
- SLC12A5 | c.1238C>A p.P413H (on ENST00000454036 / NM_001134771.2; = p.P390H on NM_020708.5) | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV54792176; called by muse, mutect2, varscan2
- SLC6A3 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765108532, CM108188; called by muse, mutect2
- SMC6 | c.1546G>T p.D516Y | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100705118; called by muse, mutect2
- SMCHD1 | c.3544C>T p.Q1182* | Nonsense Mutation (SNP) | VAF 27/147 reads (18%) | catalogued as COSV99862803; called by muse, mutect2, varscan2
- SP4 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.093); catalogued as COSV99754224; called by muse, mutect2
- SPP1 | c.280G>C p.D94H (on ENST00000395080 / NM_001040058.2; = p.D80H on NM_000582.2) | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV52952182, COSV52952603; called by muse, mutect2
- SPP1 | c.527G>C p.R176T (on ENST00000395080 / NM_001040058.2; = p.R162T on NM_000582.2) | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.131); catalogued as COSV52952853; called by muse, mutect2
- SPTBN5 | c.9109C>T p.L3037F | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as rs1336668556; called by muse, mutect2
- SRCAP | c.8059C>G p.P2687A | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs201748914; called by muse, mutect2, varscan2
- SRCIN1 | c.3500G>A p.R1167Q (on ENST00000621492; = p.R1133Q on NM_025248.3) | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs369604060; called by muse, mutect2, varscan2
- STAB1 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.095); catalogued as COSV100402247; called by muse, mutect2
- STARD3 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.666); catalogued as COSV60422605; called by muse, mutect2
- SV2A | c.1751C>A p.P584Q | Missense Mutation (SNP) | VAF 92/441 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64964911; called by muse, mutect2, varscan2
- SYT3 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as rs1188082587; called by muse, mutect2, varscan2
- TBC1D8 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65217688; called by muse, mutect2
- TEK | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 28/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101193349; called by muse, mutect2
- TG | c.4817-1G>A p.X1606_splice | Splice Site (SNP) | VAF 17/402 reads (4%) | catalogued as COSV55066828, COSV55094826; called by muse, mutect2
- TLK2 | c.1662C>G p.F554L (on ENST00000326270 / NM_001284333.2; = p.F532L on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV58305939; called by muse, mutect2
- TNFRSF13C | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1301803591; called by muse, mutect2, varscan2
- TNXB | c.3060C>G p.Y1020* | Nonsense Mutation (SNP) | VAF 9/152 reads (6%) | catalogued as rs1562863133; called by muse, mutect2
- TP73 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as rs760067757, COSV60699300; called by muse, mutect2, varscan2
- TPX2 | c.1504G>C p.D502H | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs972858335, COSV55919328; called by muse, mutect2
- TRIM58 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100825164; called by muse, mutect2
- TRPS1 | c.3404C>T p.P1135L (on ENST00000220888 / NM_001330599.2; = p.P1148L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99635829; called by muse, mutect2, varscan2
- TSBP1 | c.164G>C p.R55T | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs1472708545; called by muse, mutect2
- TTLL2 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as COSV53446058; called by muse, mutect2
- UGT1A5 | c.519G>C p.L173F | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as COSV59383635; called by muse, mutect2
- UMOD | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs1490168938, COSV56774895; called by muse, mutect2, varscan2
- VAX1 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as rs1292605878; called by muse, mutect2
- YLPM1 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.061); catalogued as rs777420279; called by muse, mutect2
- ZBTB43 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs1434213454, COSV100991506; called by muse, mutect2
- ZCCHC17 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV100704095; called by muse, mutect2
- ZFP36L2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as rs1488231952, COSV56698979, COSV56699574, COSV99143900; called by muse, mutect2
- ZKSCAN2 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as COSV60157971; called by muse, mutect2
- ZNF114 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1276912645; called by muse, mutect2, varscan2
- ZNF16 | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1411802214; called by muse, mutect2
- ZNF236 | c.3964C>G p.Q1322E | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV53492582; called by muse, mutect2
- ZNF385D | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV55747958; called by muse, mutect2
- ZNF524 | c.599G>A p.C200Y | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55607056; called by muse, mutect2, varscan2
- ZNF727 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as rs1485461796; called by muse, mutect2
- ZNF737 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101417725; called by muse, mutect2
- ZNF804A | c.983C>A p.S328* | Nonsense Mutation (SNP) | VAF 21/139 reads (15%) | catalogued as COSV56446103; called by muse, mutect2, varscan2
- ZNFX1 | c.1174C>T p.L392F | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV65575050; called by muse, mutect2
- AC011479.1 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY8 | c.3631C>A p.L1211I | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- ADH1B | c.504G>C p.E168D | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2
- AFF1 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- AHNAK | c.15787G>C p.E5263Q | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2
- AJM1 | c.2208C>G p.F736L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- AKAP9 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2
- AKAP9 | c.2926C>G p.L976V | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ALK | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 77/405 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALPK2 | c.3424C>A p.L1142M | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- ALPP | c.422A>G p.N141S | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANK1 | c.1991G>C p.G664A | Missense Mutation (SNP) | VAF 29/348 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2
- ANO9 | c.2150A>G p.K717R | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- APOB | c.9796G>A p.E3266K | Missense Mutation (SNP) | VAF 18/333 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.253); called by muse, mutect2
- ARHGAP30 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- ARSF | c.1272T>G p.I424M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2
- ASPM | c.147C>A p.F49L | Missense Mutation (SNP) | VAF 16/493 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2
- ATG16L1 | c.1456G>C p.E486Q (on ENST00000392017 / NM_030803.7; = p.E467Q on NM_017974.4) | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.075); called by muse, mutect2
- ATRAID | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 29/343 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.039); called by muse, mutect2
- B3GLCT | c.460-1G>T p.X154_splice | Splice Site (SNP) | VAF 24/147 reads (16%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.973G>T p.V325L | Missense Mutation (SNP) | VAF 13/299 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2
- BAIAP3 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- BCL11B | c.1351G>T p.G451C (on ENST00000357195 / NM_001282237.2; = p.G380C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BICRA | c.3695C>T p.P1232L | Missense Mutation (SNP) | VAF 25/368 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.35); called by muse, mutect2
- BMP2K | c.2881G>T p.E961* | Nonsense Mutation (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- BTN2A2 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 49/464 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- C2orf68 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CACNA1C | c.6136G>C p.E2046Q (on ENST00000399634 / NM_001167625.1; = p.E1975Q on NM_000719.7) | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.037); called by muse, mutect2
- CACNA2D1 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 49/323 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- CAMSAP3 | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- CANT1 | c.1041dup p.K348Qfs*103 | Frame Shift Ins (INS) | VAF 47/256 reads (18%) | called by mutect2, pindel, varscan2
- CASP2 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASTOR2 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CATSPER2 | c.717+3G>T | Splice Region (SNP) | VAF 27/248 reads (11%) | called by muse, mutect2, varscan2
- CBL | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 19/391 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); called by muse, mutect2
- CCDC136 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- CCDC14 | c.1459C>G p.Q487E (on ENST00000488653; = p.Q439E on NM_022757.5) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- CCDC151 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- CCDC152 | c.91dup p.M31Nfs*19 | Frame Shift Ins (INS) | VAF 34/107 reads (32%) | called by mutect2, pindel, varscan2
- CCDC191 | c.2173G>C p.E725Q | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC65 | c.867G>C p.E289D | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2
- CCPG1 | c.2022G>A p.W674* | Nonsense Mutation (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
- CDC26 | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CEP128 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 37/243 reads (15%) | called by muse, mutect2, varscan2
- CEP170 | c.3815G>A p.G1272E | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- CFAP54 | c.7358A>T p.D2453V | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CGREF1 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 87/439 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CHD5 | c.5756C>G p.S1919C | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); called by muse, mutect2
- CLASP1 | c.2248C>G p.Q750E | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); called by muse, mutect2
- CLGN | c.693_694+16del p.X231_splice | Splice Site (DEL) | VAF 16/178 reads (9%) | called by mutect2, pindel
- CMTR2 | c.1926_1929delinsACT p.M643Lfs*16 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | called by pindel, varscan2*
- COA1 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2
- COL11A1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 21/234 reads (9%) | called by muse, mutect2
- COPS6 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); called by muse, mutect2
- COPS7A | c.655dup p.T219Nfs*3 | Frame Shift Ins (INS) | VAF 34/108 reads (31%) | called by mutect2, varscan2
- CREBBP | c.1715G>C p.G572A | Missense Mutation (SNP) | VAF 19/404 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.493); called by muse, mutect2
- CRIP2 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CRX | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CRYBG1 | c.5746G>C p.E1916Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSMD2 | c.6808C>T p.L2270F | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2
- CSMD3 | c.4646C>G p.T1549S (on ENST00000297405 / NM_001363185.1; = p.T1445S on NM_052900.3) | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CXorf56 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2, varscan2
- DAO | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 103/314 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDB2 | c.69G>T p.R23S | Missense Mutation (SNP) | VAF 19/394 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2
- DDX42 | c.1782G>C p.E594D | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.581); called by muse, mutect2
- DDX46 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 26/201 reads (13%) | called by muse, mutect2, varscan2
- DIO2 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DNAH14 | c.5353G>A p.E1785K (on ENST00000445597; = p.E2190K on NM_001367479.1) | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2
- DNAH3 | c.8398G>C p.E2800Q | Missense Mutation (SNP) | VAF 17/400 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH8 | c.4106C>T p.T1369I | Missense Mutation (SNP) | VAF 72/288 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DNAJC13 | c.1896G>C p.Q632H | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- DPY19L2 | c.791del p.G264Efs*4 | Frame Shift Del (DEL) | VAF 16/140 reads (11%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.10807G>T p.E3603* | Nonsense Mutation (SNP) | VAF 16/294 reads (5%) | called by muse, mutect2
- DYNC2H1 | c.8175G>C p.M2725I | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.017); called by muse, mutect2
- EBF4 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- EGF | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EIF3G | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2
- ELF4 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.101); called by muse, mutect2
- ERCC3 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2
- ERICH3 | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.64); called by muse, mutect2
- EVC2 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- FAM217B | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2
- FANCB | c.744C>G p.I248M | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- FAT3 | c.2441G>A p.W814* | Nonsense Mutation (SNP) | VAF 20/248 reads (8%) | called by muse, mutect2
- FH | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRG2B | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 39/323 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- FRMD4A | c.83A>T p.D28V | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- FRRS1L | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- FSCB | c.2221C>A p.P741T | Missense Mutation (SNP) | VAF 65/251 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- GABBR2 | c.1439C>A p.P480H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GANAB | c.2556C>G p.F852L | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2
- GAREM2 | c.863G>C p.C288S | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.28); called by muse, mutect2
- GAS2L1 | c.42G>C p.K14N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- GCNT1 | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNL3L | c.1581G>C p.Q527H | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- GPAT2 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- GPR50 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- GRID2 | c.2601+1G>C p.X867_splice | Splice Site (SNP) | VAF 14/136 reads (10%) | called by mutect2, varscan2
- GRIN2A | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- GRM8 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- GTSE1 | c.2048G>A p.G683E | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.099); called by muse, mutect2
- HCK | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 18/198 reads (9%) | called by muse, mutect2
- HNRNPH3 | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.127); called by muse, mutect2
- IGKV6D-21 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- IL1RAP | c.776-1G>T p.X259_splice | Splice Site (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- IRX5 | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ISX | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGAV | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2
- ITIH1 | c.2245C>G p.Q749E | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- JMJD1C | c.3524C>T p.S1175L | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.344); called by muse, mutect2
- KATNIP | c.1619C>G p.S540C | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.35); called by muse, mutect2
- KIAA0895 | c.967C>T p.H323Y (on ENST00000297063 / NM_001100425.2; = p.H272Y on NM_015314.3) | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- KIAA1755 | c.2476C>A p.L826M | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF20A | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- KIF2C | c.1338C>G p.I446M | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- KLHL26 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KLHL41 | c.1717G>C p.D573H | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- KMT2A | c.7897C>T p.P2633S | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- KNTC1 | c.3681G>C p.K1227N | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT6B | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 30/610 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRTAP10-5 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 21/501 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2
- LAMC1 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- LAX1 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.552); called by muse, mutect2
- LIMCH1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LMX1B | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- LNPK | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- LNPK | c.463G>T p.G155* | Nonsense Mutation (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- LRP1B | c.4124G>T p.G1375V | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRIQ1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- LSR | c.599-1G>T p.X200_splice | Splice Site (SNP) | VAF 30/438 reads (7%) | called by muse, mutect2
- LTBP3 | c.1893C>G p.I631M | Missense Mutation (SNP) | VAF 29/474 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.143); called by muse, mutect2
- LTBP4 | c.2846G>T p.G949V (on ENST00000308370 / NM_001042544.1; = p.G912V on NM_003573.2) | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LUC7L2 | c.755G>C p.R252T | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.482); called by muse, mutect2
- MAGEL2 | c.1814A>T p.E605V | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MEF2D | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 13/233 reads (6%) | called by muse, mutect2
- MEGF6 | c.2451C>A p.C817* | Nonsense Mutation (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- MFSD2A | c.1092G>C p.L364F (on ENST00000372809 / NM_001136493.3; = p.L351F on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MGAM | c.2272T>C p.F758L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGME1 | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MID2 | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2
- MISP | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.408); called by muse, mutect2
- MORC1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MOV10 | c.2392G>C p.E798Q | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- MPDZ | c.1591C>A p.Q531K | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2
- MTMR4 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- MUC2 | c.680A>C p.E227A | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.07); called by muse, mutect2
- MYBPHL | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); called by muse, mutect2
- MYH8 | c.3646G>T p.V1216F | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MYH9 | c.860_861del p.H287Pfs*74 | Frame Shift Del (DEL) | VAF 52/287 reads (18%) | called by mutect2, pindel, varscan2
- MYL12B | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MYO9B | c.2250C>G p.I750M | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- MYO9B | c.3375G>C p.K1125N | Missense Mutation (SNP) | VAF 28/578 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2
- NDRG3 | c.58-1G>C p.X20_splice | Splice Site (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- NEUROD6 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 72/404 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NIPBL | c.5379G>A p.M1793I | Missense Mutation (SNP) | VAF 22/452 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.189); called by muse, mutect2
- NLRP1 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- NMT1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.15); called by muse, mutect2
- NMU | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 8/256 reads (3%) | called by muse, mutect2
- NOS1 | c.3192G>C p.Q1064H | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, varscan2
- NOSTRIN | c.507C>G p.L169= (on ENST00000317647 / NM_001039724.4; = p.L91= on NM_052946.3) | Splice Region (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2
- NOTCH4 | c.1199C>A p.P400Q | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NRDE2 | c.2017G>A p.D673N | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.075); called by muse, mutect2
- NRG2 | c.1971_1983del p.G663Afs*99 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- NRXN1 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); called by muse, mutect2
- NTRK2 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- NUFIP1 | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- OGT | c.3066G>C p.Q1022H | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- OR4K14 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- OR5AU1 | c.640A>T p.I214F | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1094C>A p.P365Q (on ENST00000374531 / NM_001037293.2; = p.P397Q on NM_053016.6) | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.765); called by muse, varscan2
- PFAS | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.164); called by muse, mutect2
- PKD1L2 | c.486C>A p.C162* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- PKHD1 | c.9803C>G p.S3268* | Nonsense Mutation (SNP) | VAF 12/317 reads (4%) | called by muse, mutect2
- PKHD1L1 | c.10948G>A p.D3650N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLA2G7 | c.1038C>T p.I346= | Splice Region (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- PLB1 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PLEC | c.10299G>C p.E3433D (on ENST00000322810 / NM_201380.4; = p.E3323D on NM_000445.5) | Missense Mutation (SNP) | VAF 26/722 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2
- PLEKHA8 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- PLEKHG4B | c.442G>A p.D148N (on ENST00000283426; = p.D504N on NM_052909.5) | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- PLPP5 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- PMFBP1 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PNMA2 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PNRC2 | c.134G>C p.R45T | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PPP4R1 | c.2194C>G p.L732V (on ENST00000400556 / NM_001042388.3; = p.L715V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- PRB2 | c.690C>A p.N230K | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, varscan2
- PRR14L | c.2575G>T p.D859Y | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- PSMA7 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.311); called by muse, mutect2
- PTGDS | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- PUM2 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PYROXD1 | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- R3HCC1L | c.14C>G p.S5* | Nonsense Mutation (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- RAB26 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2
- RAB39B | c.390G>T p.Q130H | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2
- RAB3GAP2 | c.1266G>T p.W422C | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAP2B | c.5G>C p.R2T | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.442); called by muse, mutect2
- RASSF7 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.018); called by muse, mutect2
- RBBP6 | c.4360G>A p.D1454N | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RDH10 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2
- RELCH | c.3322G>C p.D1108H | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RELN | c.9168C>A p.S3056R | Missense Mutation (SNP) | VAF 65/397 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- RELN | c.1790dup p.H597Qfs*11 | Frame Shift Ins (INS) | VAF 41/289 reads (14%) | called by mutect2, pindel, varscan2
- RGSL1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2
- RNF103 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 19/416 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.227); called by muse, mutect2
- RNF169 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2
- RPS6KA1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.175); called by muse, mutect2
- RPS6KA5 | c.249G>C p.L83F | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPS9 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.34); called by muse, mutect2
- RXFP3 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SALL1 | c.3865G>C p.E1289Q | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.837); called by muse, mutect2
- SCAF8 | c.991C>G p.Q331E | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SCN7A | c.1978A>G p.I660V | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2
- SEMA6C | c.909G>C p.L303F | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SEPTIN11 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- SERPINI1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 16/405 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2
- SETD1B | c.3608C>T p.S1203F | Missense Mutation (SNP) | VAF 34/390 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); called by muse, mutect2
- SFMBT2 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SFTPB | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SH3GL3 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- SHPRH | c.3346G>A p.E1116K (on ENST00000275233 / NM_001042683.3; = p.E1125K on NM_173082.3) | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); called by muse, mutect2
- SLC17A3 | c.136C>A p.H46N | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2
- SLC18A1 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- SLC18A3 | c.1278C>G p.I426M | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC22A12 | c.381C>A p.F127L | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SLC26A5 | c.2012G>A p.G671D | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLC2A7 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- SLC47A2 | c.567C>G p.F189L | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2
- SLC5A10 | c.1630G>A p.E544K (on ENST00000395645 / NM_001042450.4; = p.E560K on NM_152351.5) | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- SLC6A4 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- SMARCA5 | c.344C>G p.T115S | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2
- SNAPC5 | c.54G>T p.L18F | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2
- SNRNP48 | c.736A>C p.N246H | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- SNX17 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2
- SPDYE3 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 14/399 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2
- SPTBN1 | c.6623del p.H2208Pfs*22 | Frame Shift Del (DEL) | VAF 23/164 reads (14%) | called by mutect2, pindel, varscan2
- SPTLC1 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 69/289 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- SRRM5 | c.690G>C p.K230N | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); called by muse, mutect2
- SSUH2 | c.69G>C p.L23F | Missense Mutation (SNP) | VAF 13/265 reads (5%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.088); called by muse, mutect2
- STARD9 | c.6757C>T p.Q2253* | Nonsense Mutation (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- STON1-GTF2A1L | c.3373G>A p.D1125N | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYMPK | c.2935G>C p.E979Q | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- TAPBPL | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAS1R1 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2
- TBC1D25 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TBRG4 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- TCP11L1 | c.465G>C p.Q155H | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- TCP11X2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 84/607 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- TCTE3 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TDRD15 | c.4183C>T p.Q1395* | Nonsense Mutation (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- TEX14 | c.1221G>C p.Q407H (on ENST00000240361 / NM_001201457.2; = p.Q401H on NM_031272.5) | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX26 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TFAP2C | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGFBR2 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.16); called by muse, mutect2
- THOC2 | c.4304C>T p.S1435L | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TIMM23B | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- TJP2 | c.2453G>A p.R818K | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- TLR7 | c.1419G>C p.R473S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- TMIE | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.277); called by muse, mutect2
- TMPRSS11A | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TPR | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 27/211 reads (13%) | called by muse, mutect2, varscan2
- TRDN | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); called by muse, mutect2
- TRGV4 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM42 | c.1673G>C p.R558T | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2
- TRMT1L | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- TRPA1 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- TRPC4 | c.1266G>C p.W422C | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC21A | c.3840C>A p.Y1280* | Nonsense Mutation (SNP) | VAF 26/242 reads (11%) | called by muse, mutect2, varscan2
- TTC22 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- TTK | c.2181G>T p.M727I | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TTLL5 | c.2298G>T p.M766I | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, varscan2
- TTN | c.74326G>C p.E24776Q (on ENST00000591111; = p.E17352Q on NM_003319.4) | Missense Mutation (SNP) | VAF 18/469 reads (4%) | PolyPhen possibly damaging (0.572); called by muse, mutect2
- TTN | c.47946G>A p.M15982I (on ENST00000591111; = p.M8558I on NM_003319.4) | Missense Mutation (SNP) | VAF 50/446 reads (11%) | PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TUBB2B | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 17/312 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.71); called by muse, mutect2
- TXK | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2
- TYW1B | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBE2S | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- UBR4 | c.11392C>T p.Q3798* | Nonsense Mutation (SNP) | VAF 27/179 reads (15%) | called by muse, mutect2, varscan2
- URB1 | c.6286G>T p.A2096S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VEPH1 | c.1864C>G p.L622V | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- WDFY4 | c.4701G>C p.Q1567H | Missense Mutation (SNP) | VAF 13/297 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- WNK1 | c.6295G>T p.E2099* (on ENST00000315939 / NM_018979.4; = p.E1851* on NM_014823.3) | Nonsense Mutation (SNP) | VAF 32/436 reads (7%) | called by muse, mutect2
- ZC3H13 | c.2279G>C p.R760T | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); called by muse, varscan2
- ZC3H13 | c.2218G>C p.E740Q | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZFAND2A | c.302C>G p.S101* | Nonsense Mutation (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- ZFC3H1 | c.3863G>T p.W1288L | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZFHX2 | c.6973G>T p.D2325Y | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ZFHX2 | c.3118G>A p.E1040K | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- ZFP28 | c.1408C>T p.H470Y | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZFPL1 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZKSCAN7 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZMAT4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/163 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZNF225 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ZNF281 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2
- ZNF469 | c.5763G>T p.K1921N (on ENST00000437464; = p.K1949N on NM_001367624.2) | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF471 | c.1200G>C p.E400D | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- ZNF563 | c.368G>C p.R123T | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- ZNF638 | c.4156G>A p.D1386N | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF687 | c.1503C>G p.F501L | Missense Mutation (SNP) | VAF 26/305 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2
- ZNF787 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- ZZZ3 | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2
- ABCG8 | c.1293C>T p.I431= | Silent (SNP) | VAF 20/274 reads (7%) | catalogued as rs202176869; called by muse, mutect2
- ACTL8 | c.219C>G p.L73= | Silent (SNP) | VAF 33/320 reads (10%) | called by muse, mutect2, varscan2
- ADCY6 | c.2472C>T p.L824= | Silent (SNP) | VAF 28/445 reads (6%) | called by muse, mutect2
- ADGRA1 | c.597C>A p.R199= | Silent (SNP) | VAF 35/204 reads (17%) | catalogued as COSV74142623; called by muse, mutect2, varscan2
- ADGRV1 | c.9279C>T p.Y3093= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as rs368882324; ClinVar: likely benign; called by muse, mutect2, varscan2
- AGRN | c.2523G>C p.R841= | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- ALKBH4 | c.33C>T p.V11= | Silent (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- ANK1 | c.1992G>T p.G664= | Silent (SNP) | VAF 28/340 reads (8%) | catalogued as COSV55881911; called by muse, mutect2
- ANKIB1 | c.1353G>A p.L451= | Silent (SNP) | VAF 23/154 reads (15%) | called by muse, mutect2, varscan2
- ANKRD17 | c.4053G>A p.K1351= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- ANO6 | c.2718G>T p.R906= | Silent (SNP) | VAF 58/329 reads (18%) | called by muse, mutect2, varscan2
- APOC1 | c.251G>A p.*84= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV52992519; called by muse, mutect2, varscan2
- B3GNT6 | c.387C>T p.H129= | Silent (SNP) | VAF 30/229 reads (13%) | called by muse, mutect2, varscan2
- BAIAP3 | c.102C>A p.P34= | Silent (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- BCKDHB | c.903C>A p.V301= | Silent (SNP) | VAF 30/260 reads (12%) | called by muse, mutect2, varscan2
- BEGAIN | c.273G>A p.A91= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as rs747563702, COSV62068243; called by muse, mutect2, varscan2
- C6orf118 | c.534G>T p.R178= | Silent (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.2487A>G p.S829= (on ENST00000356253 / NM_001366867.1; = p.S817= on NM_000722.4) | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.1131G>C p.L377= | Silent (SNP) | VAF 14/229 reads (6%) | catalogued as COSV99765554; called by muse, mutect2
- CADPS | c.3966C>G p.L1322= | Silent (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- CARD11 | c.1665G>A p.R555= | Silent (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- CCNJ | c.450C>T p.F150= | Silent (SNP) | VAF 14/346 reads (4%) | called by muse, mutect2
- CD6 | c.31C>T p.L11= | Silent (SNP) | VAF 28/218 reads (13%) | catalogued as COSV57840345; called by muse, mutect2, varscan2
- CKAP5 | c.3222G>A p.E1074= | Silent (SNP) | VAF 14/270 reads (5%) | called by muse, mutect2
- CNKSR1 | c.1110C>A p.L370= (on ENST00000374253 / NM_001297647.2; = p.L363= on NM_006314.3) | Silent (SNP) | VAF 15/277 reads (5%) | called by muse, mutect2
- CPE | c.759G>T p.V253= | Silent (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2, varscan2
- CTAG2 | c.360G>A p.G120= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV99908981; called by muse, mutect2, varscan2
- CUX1 | c.1083G>A p.L361= (on ENST00000292535 / NM_181552.4; = p.L372= on NM_001913.5) | Silent (SNP) | VAF 10/277 reads (4%) | called by muse, mutect2
- CYB5D2 | c.342G>A p.L114= | Silent (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2
- CYP26C1 | c.357G>A p.Q119= | Silent (SNP) | VAF 13/134 reads (10%) | catalogued as rs972258158; called by muse, mutect2
- DAGLA | c.1317C>T p.I439= | Silent (SNP) | VAF 17/208 reads (8%) | called by muse, mutect2
- DCDC2 | c.363C>T p.I121= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV65833597; called by muse, mutect2
- DCTN1 | c.1821G>T p.L607= | Silent (SNP) | VAF 93/392 reads (24%) | called by muse, mutect2, varscan2
- DDX60 | c.2172G>A p.K724= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- DHX33 | c.1965G>T p.S655= | Silent (SNP) | VAF 55/337 reads (16%) | called by muse, mutect2, varscan2
- DNAAF3 | c.186G>T p.R62= (on ENST00000524407 / NM_001256715.2; = p.R109= on NM_178837.4) | Silent (SNP) | VAF 87/304 reads (29%) | catalogued as COSV101200201, COSV101200207; called by muse, mutect2, varscan2
- DNAAF5 | c.1737A>C p.A579= | Silent (SNP) | VAF 56/302 reads (19%) | called by muse, mutect2, varscan2
- DNAJB14 | c.111C>G p.L37= | Silent (SNP) | VAF 24/486 reads (5%) | called by muse, mutect2
- DNM3 | c.117C>A p.G39= | Silent (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
- DPP9 | c.1353C>T p.F451= (on ENST00000598800; = p.F480= on NM_139159.5) | Silent (SNP) | VAF 18/278 reads (6%) | catalogued as COSV99506091; called by muse, mutect2
- EIF4G1 | c.4512G>A p.L1504= (on ENST00000346169 / NM_198241.3; = p.L1309= on NM_004953.5) | Silent (SNP) | VAF 30/670 reads (4%) | called by muse, mutect2
- ERG28 | c.237C>A p.I79= | Silent (SNP) | VAF 13/131 reads (10%) | called by muse, mutect2, varscan2
- ESYT1 | c.360C>G p.L120= | Silent (SNP) | VAF 49/339 reads (14%) | catalogued as COSV99920108; called by muse, mutect2, varscan2
- EXOC2 | c.2508C>T p.L836= | Silent (SNP) | VAF 51/276 reads (18%) | catalogued as rs752351493; called by muse, varscan2
- F13B | c.54C>A p.L18= | Silent (SNP) | VAF 30/173 reads (17%) | called by muse, mutect2, varscan2
- F5 | c.1719G>T p.V573= | Silent (SNP) | VAF 28/428 reads (7%) | called by muse, mutect2
- FCGBP | c.8655C>T p.F2885= | Silent (SNP) | VAF 22/734 reads (3%) | catalogued as rs1455742229; called by muse, mutect2
- FKBP10 | c.135C>T p.V45= | Silent (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2, varscan2
- FLG | c.9273T>C p.H3091= | Silent (SNP) | VAF 81/480 reads (17%) | catalogued as rs777309084; called by muse, mutect2, varscan2
- FSCB | c.2220T>A p.P740= | Silent (SNP) | VAF 62/243 reads (26%) | called by muse, mutect2, varscan2
- FSTL5 | c.1764C>A p.T588= | Silent (SNP) | VAF 25/131 reads (19%) | called by muse, mutect2, varscan2
- GABRA3 | c.1414C>T p.L472= | Silent (SNP) | VAF 41/141 reads (29%) | called by muse, mutect2, varscan2
- GABRB2 | c.927G>A p.L309= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- GJA8 | c.231C>T p.L77= | Silent (SNP) | VAF 20/378 reads (5%) | called by muse, mutect2
- GPR137C | c.285C>T p.L95= | Silent (SNP) | VAF 32/269 reads (12%) | catalogued as rs1034737020; called by muse, mutect2, varscan2
- GSDMA | c.120G>C p.L40= | Silent (SNP) | VAF 20/364 reads (5%) | called by muse, mutect2
- GTDC1 | c.261G>T p.L87= | Silent (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2, varscan2
- H2BC13 | c.222C>T p.I74= | Silent (SNP) | VAF 41/335 reads (12%) | catalogued as COSV62440473, COSV62440942, COSV62441214; called by muse, mutect2, varscan2
- H3-3A | c.57G>A p.K19= | Silent (SNP) | VAF 38/214 reads (18%) | called by muse, mutect2, varscan2
- HIPK2 | c.3381G>T p.A1127= | Silent (SNP) | VAF 31/258 reads (12%) | catalogued as COSV69207969; called by muse, mutect2, varscan2
- HSPA1A | c.1674C>G p.L558= | Silent (SNP) | VAF 30/732 reads (4%) | catalogued as rs371873691; called by muse, mutect2
- IGF1 | c.120C>T p.L40= | Silent (SNP) | VAF 48/288 reads (17%) | catalogued as rs376414192; called by muse, mutect2, varscan2
- IGSF10 | c.5037C>A p.T1679= | Silent (SNP) | VAF 16/80 reads (20%) | called by muse, varscan2
- ILVBL | c.1092C>A p.L364= | Silent (SNP) | VAF 36/234 reads (15%) | called by muse, mutect2, varscan2
- INAVA | c.243C>T p.F81= | Silent (SNP) | VAF 21/262 reads (8%) | called by muse, mutect2
- INTS1 | c.3351G>A p.L1117= | Silent (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- ITIH6 | c.756G>T p.V252= | Silent (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- KCNA4 | c.294G>T p.R98= | Silent (SNP) | VAF 26/247 reads (11%) | catalogued as rs1320966017; called by muse, mutect2
- KHDC3L | c.366C>T p.L122= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs933529284; called by muse, mutect2, varscan2
- KIF7 | c.1645C>A p.R549= | Silent (SNP) | VAF 17/216 reads (8%) | catalogued as rs866153959, COSV67997351; called by muse, mutect2
- LCE1F | c.171G>T p.G57= | Silent (SNP) | VAF 55/367 reads (15%) | catalogued as COSV100542724; called by muse, mutect2, varscan2
- LRP2 | c.13953A>G p.E4651= | Silent (SNP) | VAF 42/314 reads (13%) | catalogued as COSV99787326; called by muse, varscan2
- LRRTM2 | c.132C>T p.L44= | Silent (SNP) | VAF 15/222 reads (7%) | catalogued as COSV51219724, COSV51224681; called by muse, mutect2
- LURAP1 | c.612G>A p.E204= | Silent (SNP) | VAF 16/193 reads (8%) | catalogued as rs189814441, COSV64338115; called by muse, mutect2
- MAGEE2 | c.432G>A p.L144= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs369383225; called by muse, mutect2, varscan2
- MGST3 | c.126C>T p.I42= | Silent (SNP) | VAF 14/391 reads (4%) | called by muse, mutect2
- MS4A2 | c.546A>T p.V182= | Silent (SNP) | VAF 36/296 reads (12%) | called by muse, mutect2, varscan2
- MUSK | c.2446C>A p.R816= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV99504793; called by muse, varscan2
- MYOD1 | c.864C>T p.P288= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as rs1307453454, COSV100000155; called by muse, mutect2
- NF1 | c.5565C>G p.L1855= (on ENST00000358273 / NM_001042492.3; = p.L1834= on NM_000267.3) | Silent (SNP) | VAF 10/131 reads (8%) | called by muse, mutect2
- NOL4 | c.1656C>A p.T552= | Silent (SNP) | VAF 34/130 reads (26%) | called by muse, mutect2, varscan2
- NSD3 | c.4140C>T p.F1380= | Silent (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- OAS3 | c.2319G>T p.V773= | Silent (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- OR4A16 | c.634C>T p.L212= | Silent (SNP) | VAF 10/275 reads (4%) | catalogued as COSV59044644; called by muse, mutect2
- OR5D18 | c.936T>G p.S312= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- OR5L1 | c.606G>A p.V202= | Silent (SNP) | VAF 24/171 reads (14%) | called by muse, mutect2, varscan2
- OSBPL9 | c.1134C>G p.L378= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV100542786; called by muse, mutect2
- PCDHGA2 | c.1701C>T p.F567= | Silent (SNP) | VAF 20/362 reads (6%) | catalogued as COSV53979840; called by muse, mutect2
- PDE1B | c.465C>G p.L155= | Silent (SNP) | VAF 26/240 reads (11%) | called by muse, mutect2, varscan2
- PIBF1 | c.138C>T p.I46= | Silent (SNP) | VAF 11/272 reads (4%) | called by muse, mutect2
- PIK3CD | c.2067G>A p.L689= | Silent (SNP) | VAF 22/444 reads (5%) | called by muse, mutect2
- PIP5K1C | c.1299G>A p.E433= | Silent (SNP) | VAF 56/279 reads (20%) | called by muse, mutect2, varscan2
- PKHD1 | c.3393G>C p.A1131= | Silent (SNP) | VAF 15/376 reads (4%) | called by muse, mutect2
- PLEC | c.13803G>A p.L4601= (on ENST00000322810 / NM_201380.4; = p.L4491= on NM_000445.5) | Silent (SNP) | VAF 47/538 reads (9%) | catalogued as rs1255647569; called by muse, mutect2
- PLXNA4 | c.2643G>A p.E881= | Silent (SNP) | VAF 10/263 reads (4%) | catalogued as COSV58126757; called by muse, mutect2
- PNP | c.525C>G p.L175= | Silent (SNP) | VAF 44/315 reads (14%) | catalogued as rs779697422; called by muse, varscan2
- PNP | c.573C>G p.T191= | Silent (SNP) | VAF 24/158 reads (15%) | called by muse, varscan2
- POLE | c.2778G>A p.E926= | Silent (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2, varscan2
- POTEB3 | c.1353G>A p.K451= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as rs1203528893; called by muse, mutect2, varscan2
- PREX2 | c.4734G>A p.K1578= | Silent (SNP) | VAF 22/241 reads (9%) | catalogued as COSV55759704, COSV55790642; called by muse, mutect2
- PSG1 | c.357C>A p.S119= | Silent (SNP) | VAF 18/197 reads (9%) | catalogued as COSV99741042; called by muse, mutect2
- PTGES2 | c.114C>T p.F38= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- PYGM | c.2130C>T p.F710= | Silent (SNP) | VAF 46/374 reads (12%) | catalogued as CD941765; called by muse, mutect2, varscan2
- RINT1 | c.381C>T p.L127= | Silent (SNP) | VAF 18/338 reads (5%) | called by muse, mutect2
- RNF213 | c.15474G>C p.L5158= | Silent (SNP) | VAF 12/324 reads (4%) | catalogued as COSV60400604; called by muse, mutect2
- RNPEPL1 | c.1293G>A p.V431= | Silent (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- RPS6KB1 | c.696G>A p.V232= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV56676733; called by muse, mutect2, varscan2
- SAMD9 | c.3276C>T p.F1092= | Silent (SNP) | VAF 26/304 reads (9%) | called by muse, mutect2
- SELENOW | c.174C>T p.H58= | Silent (SNP) | VAF 12/276 reads (4%) | catalogued as rs1568608058; called by muse, mutect2
- SERPINB11 | c.963A>T p.S321= | Silent (SNP) | VAF 26/96 reads (27%) | called by muse, mutect2, varscan2
- SERPINB3 | c.1002G>A p.V334= | Silent (SNP) | VAF 14/173 reads (8%) | called by muse, mutect2
- SHANK3 | c.2610C>T p.L870= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs1158278512, COSV53188468; called by muse, mutect2
- SLC12A9 | c.2019G>A p.G673= | Silent (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- SLC25A1 | c.531G>C p.L177= | Silent (SNP) | VAF 28/198 reads (14%) | catalogued as rs782423784; called by muse, mutect2, varscan2
- SLC25A32 | c.618G>A p.L206= | Silent (SNP) | VAF 11/206 reads (5%) | called by muse, mutect2
- SLITRK3 | c.1677C>T p.L559= | Silent (SNP) | VAF 42/318 reads (13%) | catalogued as rs780312673; called by muse, mutect2, varscan2
- SNX8 | c.153C>T p.P51= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs768321398; called by muse, mutect2, varscan2
- SOX11 | c.282G>A p.E94= | Silent (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- SOX14 | c.531C>T p.F177= | Silent (SNP) | VAF 29/171 reads (17%) | catalogued as rs1379316254, COSV100048202; called by muse, mutect2, varscan2
- SPON1 | c.2067G>A p.V689= | Silent (SNP) | VAF 21/256 reads (8%) | called by muse, mutect2
- SPTBN2 | c.1773C>T p.S591= | Silent (SNP) | VAF 35/274 reads (13%) | catalogued as rs769837002; called by muse, mutect2, varscan2
- SSC5D | c.441G>A p.L147= | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- STAT1 | c.1383C>G p.V461= | Silent (SNP) | VAF 23/474 reads (5%) | called by muse, mutect2
- SYT11 | c.207C>G p.L69= | Silent (SNP) | VAF 21/429 reads (5%) | catalogued as COSV64175172, COSV64176124; called by muse, mutect2
- SYTL1 | c.324G>A p.R108= | Silent (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- TAF15 | c.501G>A p.V167= (on ENST00000605844 / NM_139215.3; = p.V164= on NM_003487.4) | Silent (SNP) | VAF 22/274 reads (8%) | called by muse, mutect2
- TASOR | c.207C>G p.L69= | Silent (SNP) | VAF 9/154 reads (6%) | catalogued as COSV62927990; called by muse, mutect2
- TBX1 | c.1107G>A p.V369= | Silent (SNP) | VAF 19/272 reads (7%) | catalogued as COSV61547917; called by muse, mutect2
- TEX14 | c.1413G>A p.G471= (on ENST00000240361 / NM_001201457.2; = p.G465= on NM_031272.5) | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- TEX45 | c.468C>A p.S156= | Silent (SNP) | VAF 53/187 reads (28%) | called by muse, mutect2, varscan2
- TMEM63B | c.282G>T p.V94= | Silent (SNP) | VAF 24/135 reads (18%) | called by muse, mutect2, varscan2
- USP34 | c.6885A>G p.P2295= | Silent (SNP) | VAF 50/171 reads (29%) | called by muse, mutect2, varscan2
- USP36 | c.1047C>T p.L349= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV61754968; called by muse, mutect2
- WDR81 | c.1596G>T p.L532= | Silent (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
- WNT9B | c.375C>T p.A125= | Silent (SNP) | VAF 14/214 reads (7%) | catalogued as rs368158766; called by muse, mutect2
- XDH | c.1074C>A p.I358= | Silent (SNP) | VAF 49/451 reads (11%) | called by muse, mutect2, varscan2
- ZFHX4 | c.4218C>T p.F1406= | Silent (SNP) | VAF 10/249 reads (4%) | catalogued as COSV51493475; called by muse, mutect2
- ZFHX4 | c.8505G>T p.P2835= | Silent (SNP) | VAF 48/152 reads (32%) | catalogued as COSV50505185, COSV50508878; called by muse, mutect2, varscan2
- ZMYM3 | c.3537C>A p.L1179= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs764835649, COSV58741194; called by mutect2, varscan2
- ZNF85 | c.960C>T p.G320= | Silent (SNP) | VAF 17/165 reads (10%) | catalogued as rs879052423; called by muse, mutect2, varscan2
- ZNF93 | c.294G>C p.V98= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- AC008080.1 | n.517G>A | RNA (SNP) | VAF 7/137 reads (5%) | called by muse, mutect2
- AC018638.4 | n.761C>T | RNA (SNP) | VAF 50/514 reads (10%) | called by muse, mutect2, varscan2
- AC079612.1 | n.304C>A | RNA (SNP) | VAF 64/428 reads (15%) | called by mutect2, varscan2
- AC079612.1 | n.305C>A | RNA (SNP) | VAF 63/432 reads (15%) | called by muse, mutect2, varscan2
- AC136759.1 | n.742G>A | RNA (SNP) | VAF 18/294 reads (6%) | called by muse, mutect2
- ACSF3 | c.1366+3332G>A | Intron (SNP) | VAF 22/95 reads (23%) | catalogued as rs1288672208; called by muse, varscan2
- AMPD2 | c.91+136C>T | Intron (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- AMT | c.*752C>G | 3'UTR (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- AP000769.3 | chr11:65501322 del AAACAAG | 5'Flank (DEL) | VAF 18/226 reads (8%) | called by mutect2, pindel
- AP000769.3 | chr11:65502369 C>T | 5'Flank (SNP) | VAF 26/126 reads (21%) | catalogued as rs566979345; called by muse, mutect2, varscan2
- ARHGAP24 | c.391+7220C>T | Intron (SNP) | VAF 8/181 reads (4%) | called by muse, mutect2
- ARHGAP25 | c.*69G>A | 3'UTR (SNP) | VAF 32/312 reads (10%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+499C>T | Intron (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- C11orf80 | c.1600+753G>C | Intron (SNP) | VAF 17/186 reads (9%) | called by muse, mutect2
- C1orf229 | n.507C>T | RNA (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- C5orf60 | n.992G>A | RNA (SNP) | VAF 8/147 reads (5%) | called by muse, mutect2
- CBLIF | c.-7G>A | 5'UTR (SNP) | VAF 26/362 reads (7%) | called by muse, mutect2
- CCDC144CP | n.2467C>T | RNA (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- CD40 | chr20:46118301 C>T | 5'Flank (SNP) | VAF 29/253 reads (11%) | catalogued as COSV64848007; called by muse, mutect2, varscan2
- CDH18 | c.1630+127T>A | Intron (SNP) | VAF 31/77 reads (40%) | catalogued as rs954158687; called by muse, varscan2
- CDKL1 | c.742-1568G>T | Intron (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- COMMD8 | c.-9C>G | 5'UTR (SNP) | VAF 8/106 reads (8%) | catalogued as COSV101055680; called by muse, mutect2
- CYP27A1 | c.*45C>G | 3'UTR (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- DCAF17 | c.*2089C>T | 3'UTR (SNP) | VAF 20/280 reads (7%) | catalogued as rs756605585; called by muse, mutect2
- DGKZ | c.934-65del | Intron (DEL) | VAF 18/176 reads (10%) | called by mutect2, pindel
- ECHDC1 | c.515+1255G>T | Intron (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- EIF4G3 | c.1495+136C>T | Intron (SNP) | VAF 16/154 reads (10%) | catalogued as rs1474333203; called by muse, mutect2
- EPB41 | c.2185-39C>T | Intron (SNP) | VAF 27/199 reads (14%) | called by muse, mutect2, varscan2
- FAM122B | c.*849G>A | 3'UTR (SNP) | VAF 5/87 reads (6%) | catalogued as COSV99980180; called by muse, mutect2
- FAM53C | chr5:138338111 G>C | 5'Flank (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- FAM90A20P | n.703G>T | RNA (SNP) | VAF 74/492 reads (15%) | catalogued as rs751452765; called by muse, mutect2, varscan2
- GALNT16 | c.1539+13G>A | Intron (SNP) | VAF 26/184 reads (14%) | called by muse, mutect2, varscan2
- GP6 | c.*623C>G | 3'UTR (SNP) | VAF 23/416 reads (6%) | called by muse, mutect2
- GTF2IRD2P1 | n.1192G>T | RNA (SNP) | VAF 45/484 reads (9%) | called by muse, varscan2
- H2BP2 | n.1061+1831G>T | Intron (SNP) | VAF 31/496 reads (6%) | called by muse, mutect2
- HGF | c.482+1204C>T | Intron (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- HNRNPLL | c.-232C>A | 5'UTR (SNP) | VAF 51/251 reads (20%) | catalogued as rs200327825; called by muse, mutect2, varscan2
- IGHV3-53 | c.-4C>T | 5'UTR (SNP) | VAF 12/192 reads (6%) | catalogued as rs1555545343; called by muse, mutect2
- KCNMA1 | c.-41G>A | 5'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- KCNQ1 | c.*70C>G | 3'UTR (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- KDM2B | c.*147C>T | 3'UTR (SNP) | VAF 23/327 reads (7%) | catalogued as rs782116976, COSV65639394; called by muse, mutect2
- KLF6 | c.*1400G>C | 3'UTR (SNP) | VAF 10/212 reads (5%) | catalogued as rs911494415; called by muse, mutect2
- KLHL7 | c.-57G>C | 5'UTR (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- LENG8 | c.*2656C>G | 3'UTR (SNP) | VAF 11/280 reads (4%) | catalogued as rs978525615; called by muse, mutect2
- LINC01101 | n.326G>C | RNA (SNP) | VAF 65/341 reads (19%) | called by muse, mutect2, varscan2
- LINC01387 | n.152C>T | RNA (SNP) | VAF 28/99 reads (28%) | catalogued as rs1014798047; called by muse, mutect2, varscan2
- LMNA | c.1968+42C>A | Intron (SNP) | VAF 67/351 reads (19%) | called by muse, mutect2, varscan2
- LRP4 | c.4448+32G>T | Intron (SNP) | VAF 47/480 reads (10%) | catalogued as COSV101066108; called by muse, mutect2
- MED23 | c.*38G>A | 3'UTR (SNP) | VAF 30/219 reads (14%) | catalogued as rs754340396; called by muse, mutect2, varscan2
- MIR124-2 | n.8T>A | RNA (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- MPPED2 | c.311-9303C>T | Intron (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- MSC | c.534+148C>A | Intron (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- NDUFA5 | c.21+101C>T | Intron (SNP) | VAF 19/330 reads (6%) | catalogued as COSV63251340; called by muse, mutect2
- NSMAF | c.59+253C>T | Intron (SNP) | VAF 35/188 reads (19%) | catalogued as rs529977784; called by muse, mutect2, varscan2
- OFCC1 | n.68C>T | RNA (SNP) | VAF 11/165 reads (7%) | catalogued as rs1395196660; called by muse, mutect2
- PARP8 | c.91+408C>T | Intron (SNP) | VAF 32/269 reads (12%) | catalogued as rs1332610888; called by muse, mutect2, varscan2
- PAXBP1 | c.2334+169G>C | Intron (SNP) | VAF 13/164 reads (8%) | called by muse, mutect2
- PAXBP1 | c.1384-930C>T | Intron (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- PCNP | c.-28G>T | 5'UTR (SNP) | VAF 17/72 reads (24%) | called by muse, varscan2
- PLAU | c.57+156T>A | Intron (SNP) | VAF 40/194 reads (21%) | called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.-38C>A | 5'UTR (SNP) | VAF 5/51 reads (10%) | catalogued as rs1445637986, COSV57965177; called by muse, mutect2, varscan2
- POM121 | chr7:72948894 G>C | 3'Flank (SNP) | VAF 18/318 reads (6%) | catalogued as COSV57510120; called by muse, mutect2
- PPFIA2 | c.645+67C>A | Intron (SNP) | VAF 38/132 reads (29%) | called by muse, mutect2, varscan2
- RAB18 | c.*621C>G | 3'UTR (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- RASL11A | c.-2C>T | 5'UTR (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158663 C>A | 5'Flank (SNP) | VAF 56/145 reads (39%) | called by muse, mutect2, varscan2
- RNF170 | c.*2436G>C | 3'UTR (SNP) | VAF 9/182 reads (5%) | catalogued as rs1418755008; called by muse, mutect2
- RPL34-DT | n.1088+453G>A | Intron (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- RPN2 | c.*75G>T | 3'UTR (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- SGCA | c.983+988G>C | Intron (SNP) | VAF 24/194 reads (12%) | called by muse, mutect2, varscan2
- SGCE | c.218-19C>G | Intron (SNP) | VAF 15/204 reads (7%) | called by muse, mutect2
- SLC11A2 | c.*1133C>G | 3'UTR (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- SLURP2 | c.*35C>A | 3'UTR (SNP) | VAF 16/117 reads (14%) | catalogued as COSV100235631; called by muse, mutect2, varscan2
- SMIM4 | c.*27C>A | 3'UTR (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- TAF1D | c.-146G>A | 5'UTR (SNP) | VAF 30/231 reads (13%) | called by muse, mutect2, varscan2
- TBC1D8B | c.1203+21C>T | Intron (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- THAP10 | c.-78C>T | 5'UTR (SNP) | VAF 10/159 reads (6%) | catalogued as COSV51437291; called by muse, mutect2
- TMEM99 | n.523C>T | RNA (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- UBE2E3 | c.245+3261C>T | Intron (SNP) | VAF 11/209 reads (5%) | called by muse, mutect2
- UGT3A1 | c.94+48del | Intron (DEL) | VAF 44/133 reads (33%) | called by mutect2, pindel, varscan2
- UQCRB | c.259-97A>T | Intron (SNP) | VAF 53/157 reads (34%) | called by muse, mutect2, varscan2
- VEGFA | chr6:43784647 G>C | 3'Flank (SNP) | VAF 15/402 reads (4%) | called by muse, mutect2
- WDR62 | c.269+133G>C | Intron (SNP) | VAF 43/264 reads (16%) | called by muse, mutect2, varscan2
- WNT4 | c.313+2248G>A | Intron (SNP) | VAF 50/372 reads (13%) | called by muse, mutect2, varscan2
